Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAW2, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAW2-01A (Primary Tumor).

ICD O-3

Carcinoma, hepatocellular NOS

817013

Site Liver C22.0

QW 4/23/14

DIAGNOSIS:

Liver, left, hemihepatectomy:

Hepatocellular carcinoma, S2

- 1) Post-chemoembolization status: absent
- 2) Size of tumor: 5.5x4.8x4.2cm
- 3) Gross type: expanding nodular
- 4) Satellite nodule: absent
- 5) Histologic type: trabecular and pseudoglandular
- 6) Cell type: classic cell group
- 7) Edmondson and Steiner's histologic grade:
The worst differentiation: 2
The major differentiation: 2
- 8) Fatty change: absent
- 9) Hemorrhage/necrosis: absent
- 10) Tumor necrosis: absent
- 11) Vascular invasion(microscopic): absent
- 12) Capsule formation: complete
- 13) Infiltration of capsule: absent
- 14) Septal formation: present
- 15) Involvement of a major branch of the portal vein: absent
- 16) Involvement of a major branch of the hepatic vein: absent
- 17) Bile duct invasion: absent
- 18) Serosal invasion: absent
- 19) Surgical margin: clear (safety margin: 0.8cm)
- 20) Intrahepatic metastasis: absent
- 21) Multicentric occurrence: absent
- 22) Pathologic stage: AJCC (pT1), (pT2)
- 23) Related biopsy: none
- 24) Additional pathologic findings
- a) Cirrhosis: present, inactive, alcoholic
- b) Dysplasia: absent

Liver, S7, tumorectomy:

Necrotizing granulomatous inflammation with heavy eosinophilic infiltration

Gallbladder, cholecystectomy:

Chronic cholecystitis

Source: NCI Genomic Data Commons file 8d2651ba-f0d6-4c06-8689-f1b0c3ee19f7 (TCGA-DD-AAW2.74C2D5FA-1FDF-424A-BEE2-DE602A4F6DA7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).